Gene-level copy-number profile of tumor specimen TCGA-QB-AA9O-06A from TCGA case TCGA-QB-AA9O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.9 years (27,009 days).
Specimen TCGA-QB-AA9O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.0cd08a4d-7439-4b6e-8d5f-7dd25d145d01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QB-AA9O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b6ad0b73-c1d5-4b46-95da-ebd88b2baebb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 840; copy number 2: 8,910; copy number 3: 23,095; copy number 4: 20,112; copy number 5: 1,909; copy number 6: 4,221; copy number 7: 403; copy number 8: 231.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QB-AA9O-06A-11D-A396-01): tumor purity 0.62, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–26,644,595, 81 genes (broad region; genes not listed).
- chr9:104,781,006–104,928,155, 1 gene (within-gene range 0–3): ABCA1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 634 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:68,330,955–84,164,564, 231 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:86,866,415–104,484,465, 316 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:123,013,170–126,008,930, 70 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:125,900,951–125,901,054, 1 gene, copy number 7: RNU6-442P.
- chr8:135,234,131–138,497,261, 16 genes, copy number 7 (within-gene range 6–7): LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.

Autosomal genes at a single copy (total copy number 1): 561. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
